Gene-level copy-number profile of tumor specimen TCGA-94-8035-01A from TCGA case TCGA-94-8035, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 64.1 years (23,399 days).
Specimen TCGA-94-8035-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.cc71b8e9-1d85-4151-87d4-1cd9931a9b37.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-94-8035-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1f6f03d9-8905-47a4-86e9-f7e0abf4010a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 8; copy number 2: 15,968; copy number 3: 3,479; copy number 4: 36,069; copy number 5: 1,191; copy number 6: 1,896; copy number 7: 183; copy number 8: 122; copy number 9: 37; copy number 11: 70; copy number 12: 557; copy number 13: 164; copy number 14: 52; copy number 17: 2; copy number 23: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-94-8035-01A-11D-2243-01): tumor purity 0.48, ploidy 1.79, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:66,997,168–67,654,612, 6 genes: AC020655.1, KBTBD8, MIR4272, AC114401.1, SUCLG2, NDUFB4P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 897 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:165,122,713–192,917,856, 457 genes, copy number 9–14 (within-gene range 7–14) (broad region; genes not listed).
- chr4:51,843,000–77,083,126, 419 genes, copy number 11–17 (broad region; genes not listed).
- chr13:27,162,855–27,917,298, 21 genes, copy number 11–23 (within-gene range 6–23): USP12-AS1, USP12-AS2, LINC02340, LINC00412, RPL21, SNORD102, SNORA27, RASL11A, RNU6-70P, LINC01079, RNY1P1, GTF3A, MTIF3, RNU6-63P, LNX2, POLR1D, AL136439.1, NPM1P4, GSX1, PLUT, RNU6-73P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
